Gene-level copy-number profile of tumor specimen TARGET-40-PAMEKS-01A from TARGET case TARGET-40-PAMEKS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.8 years (3,942 days).
Specimen TARGET-40-PAMEKS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.08f22f7f-79c6-54a9-a178-6386e048d0c7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMEKS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 443 have no estimate.
https://portal.gdc.cancer.gov/files/2307d565-a1de-4695-8136-8f5a29a0c9c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,836; copy number 2: 20,297; copy number 3: 12,138; copy number 4: 14,960; copy number 5: 5,741; copy number 6: 895; copy number 7: 1,284; copy number 8: 1,413; copy number 9: 229; copy number 10: 128; copy number 11: 154; copy number 12: 46; copy number 13: 10; copy number 16: 2; copy number 19: 44; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:67,360,460–67,654,612, 1 gene (within-gene range 0–3): SUCLG2.
- chr16:72,821,933–72,821,992, 1 gene: RNU7-71P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,945 genes in 58 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,050,817–166,167,001, 806 genes, copy number 5–20 (broad region; genes not listed).
- chr1:167,379,108–167,518,610, 5 genes, copy number 5 (within-gene range 3–5): AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2.
- chr1:167,627,385–170,304,358, 66 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:170,460,453–176,447,919, 118 genes, copy number 6–9 (broad region; genes not listed).
- chr1:180,632,022–181,061,938, 10 genes, copy number 13 (within-gene range 3–13): XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1.
- chr1:182,182,730–185,015,067, 60 genes, copy number 6–9: YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72.
- chr5:58,198–1,933,985, 74 genes, copy number 6 (broad region; genes not listed).
- chr5:14,664,664–18,236,196, 82 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:30,248,350–45,895,970, 259 genes, copy number 5–9 (broad region; genes not listed).
- chr6:655,939–58,438,364, 1,517 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:94,907,202–96,110,322, 17 genes, copy number 5 (within-gene range 4–5): PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1.
- chr7:100,200,653–103,989,658, 146 genes, copy number 5 (within-gene range 4–7) (broad region; genes not listed).
- chr7:110,662,644–159,233,377, 964 genes, copy number 5–8 (within-gene range 5–11) (broad region; genes not listed).
- chr8:43,018,424–64,973,848, 308 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr8:66,021,553–69,178,189, 53 genes, copy number 5–7: DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1.
- chr8:79,762,371–89,833,564, 155 genes, copy number 5–10 (broad region; genes not listed).
- chr8:91,209,494–138,083,657, 650 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr8:138,063,268–140,458,579, 14 genes, copy number 6 (within-gene range 4–6): AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13.
- chr9:75,890,644–76,651,203, 7 genes, copy number 6 (within-gene range 4–6): PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87.
- chr9:77,716,097–78,330,093, 8 genes, copy number 6: GNAQ, AL353705.2, RN7SKP59, ASS1P3, AL353705.1, AL353705.3, CEP78, PSAT1.
- chr11:2,295,628–3,166,739, 33 genes, copy number 5: C11orf21, TSPAN32, RNU6-878P, CD81-AS1, RPL26P30, Y_RNA, CD81, TSSC4, AC124057.1, TRPM5, KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4, AC021424.2, COX6CP18, KCNQ1-AS1, KCNQ1DN, AC013791.1, CDKN1C, SLC22A18AS, SLC22A18, PHLDA2, NAP1L4, SNORA54, AC131971.1, CARS1, CARS1-AS1, RNU1-91P, AC108448.3, AC108448.2, OSBPL5.
- chr11:18,836,304–19,060,717, 11 genes, copy number 5: MRGPRX8P, MRGPRX7P, AC023078.2, MRGPRX6P, MRGPRX5P, MRGPRX1, AC023078.1, MRGPRX11P, MRGPRX10P, MRGPRX9P, MRGPRX2.
- chr14:18,333,726–19,957,996, 83 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:22,773,222–52,774,989, 538 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:19,878,555–35,238,197, 496 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr15:98,319,687–99,716,466, 30 genes, copy number 6 (within-gene range 2–6): AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A.
- chr17:997,129–7,687,538, 336 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:13,095,695–22,706,703, 416 genes, copy number 7–8 (broad region; genes not listed).
- chr18:47,390–5,004,537, 101 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:5,081,171–13,652,755, 212 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:14,903,580–15,330,282, 17 genes, copy number 5 (within-gene range 3–5): AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:8,173,272–14,171,267, 347 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr19:14,689,801–15,023,276, 17 genes, copy number 6 (within-gene range 2–6): ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105.
- chr19:20,535,825–21,125,270, 22 genes, copy number 5: ZNF737, AC010636.2, VN1R78P, AC010636.1, ZNF626, AC010329.5, AC010329.2, AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P.
- chr19:21,677,550–22,052,370, 14 genes, copy number 8: MTDHP3, MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1.
- chr19:23,255,053–30,957,192, 104 genes, copy number 5–8 (broad region; genes not listed).
- chr20:760,080–25,058,980, 474 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:28,563,850–30,403,384, 27 genes, copy number 9–11: FRG1CP, FRG1DP, 5_8S_rRNA, DUX4L32, PCMTD1P7, DUX4L33, DUX4L34, FRG2EP, RARRES2P11, AGGF1P10, DUX4L35, FRG1EP, FAM242B, Y_RNA, CFTRP2, 5_8S_rRNA, CDC27P3, RNA5SP532, DUX4L37, CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1.
- chr20:40,121,041–64,033,100, 581 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr21:12,999,676–46,665,124, 735 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 583. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
